Gene-level copy-number profile of tumor specimen TCGA-RS-A6TO-01A from TCGA case TCGA-RS-A6TO, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 82.4 years (30,104 days).
Specimen TCGA-RS-A6TO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.65efbede-5d9b-43e1-82e0-c6c1cb0d0cd6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-RS-A6TO-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f7ecfe8f-6dcd-4fb8-abf1-eaf322689bd9

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 2: 6,028; copy number 3: 28,858; copy number 4: 22,315; copy number 5: 19; copy number 6: 378; copy number 7: 1,561; copy number 10: 27; copy number 11: 326; copy number 13: 22; copy number 14: 6; copy number 18: 221; copy number 19: 6; copy number 21: 20; copy number 29: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-RS-A6TO-01A-32D-A34I-01): tumor purity 0.42, ploidy 3.57, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,898,423–141,208,376, 4 genes: LRRC57P1, Y_RNA, RNU6-904P, RPS16P3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,218 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:46,579,213–145,066,685, 1,532 genes, copy number 7 (broad region; genes not listed).
- chr13:94,436,811–114,337,626, 317 genes, copy number 11 (broad region; genes not listed).
- chr17:26,981,694–27,352,828, 15 genes, copy number 7: AC069061.1, AC069061.2, PDLIM1P3, GTF2IP6, VN1R71P, TUFMP1, AC129926.2, AC129926.1, RPL34P31, RPS16P8, AC026254.1, MIR4522, WSB1, AC026254.2, SYPL1P2.
- chr17:74,203,582–74,546,115, 14 genes, copy number 7: RPL38, MGC16275, TTYH2, AC100786.1, DNAI2, AC103809.1, KIF19, BTBD17, GPR142, RNA5SP448, GPRC5C, CD300A, CD300LB, CD300C.
- chr17:75,370,947–75,879,546, 27 genes, copy number 10: AC011933.2, AC011933.3, MIR3678, RNU6-938P, Y_RNA, TMEM94, MIR6785, CASKIN2, TSEN54, LLGL2, MYO15B, RECQL5, SMIM5, SMIM6, SAP30BP, AC087749.2, AC087749.1, ITGB4, GALK1, H3-3B, MIR4738, UNK, AC087289.1, UNC13D, WBP2, TRIM47, AC087289.5.
- chr19:27,793,431–27,984,984, 1 gene, copy number 18 (within-gene range 2–18): AC006504.5.
- chr19:27,849,635–29,841,818, 44 genes, copy number 11–29: AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2.
- chr19:34,675,717–36,105,108, 110 genes, copy number 13–18 (broad region; genes not listed).
- chr19:36,604,817–37,304,395, 26 genes, copy number 14–21 (within-gene range 3–21): ZNF382, ZNF461, AC074138.1, LINC01534, ZNF567, ZNF850, AC020928.1, AC020928.2, ZNF790-AS1, ZNF790, ZNF345, Y_RNA, ZNF829, RPL31P61, ZNF568, ZNF420, AC010632.3, AC010632.1, AC010632.2, AC012309.1, ZNF585A, AC012309.2, ZNF585B, ZNF383, AC016590.1, LINC01535.
- chr19:38,941,401–39,686,373, 46 genes, copy number 18 (within-gene range 3–18): FBXO17, AC011455.8, FBXO27, AC010605.1, ACP7, PAK4, AC011443.1, NCCRP1, SYCN, IFNL3P1, IFNL3, IFNL4, MSRB1P1, IFNL4P1, IFNL2, IFNL1, LRFN1, GMFG, AC011445.1, SAMD4B, RN7SL566P, PAF1, MED29, ZFP36, MIR4530, PLEKHG2, RPS16, SUPT5H, TIMM50, DLL3, SELENOV, EID2B, AC011500.3, TDGF1P7, EID2, AC011500.2, AC011500.1, RPS29P24, RPS29P25, RPS29P26, LGALS13, AC005176.2, AC005176.1, RPS29P30, LGALS16, LGALS17A.
- chr19:42,949,503–43,171,515, 6 genes, copy number 19 (within-gene range 2–22): CEACAMP7, AC004784.1, PSG11, CEACAMP8, PSG2, CEACAMP9.
- chr19:43,607,224–45,038,198, 80 genes, copy number 18 (within-gene range 3–18) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
